CCDI case PBBKTB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/bf76b1b6-a052-4c42-93ac-f8a27148b207

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.0 years (3,282 days).

Biospecimens (3 samples)
- Sample 0DAZOH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAZOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAZOJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
